Somatic mutation profile of tumor specimen TARGET-10-PATVDA-03A (aliquot TARGET-10-PATVDA-03A-01D) from TARGET case TARGET-10-PATVDA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (780 days).
Specimen TARGET-10-PATVDA-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a78675a0-9625-4cfc-b705-7ffe31c37f43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATVDA-10A (Blood Derived Normal), aliquot TARGET-10-PATVDA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ce94414-a686-4b7c-b0bb-74b8722d7f69

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 2, 5'Flank 1, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARMIL2 | c.2522C>A p.A841E | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.068); catalogued as COSV58031071; called by muse, mutect2
- PPP1R13B | c.2899G>T p.V967F | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161808831; called by muse, mutect2
- SHC3 | c.1428G>T p.E476D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as rs1326031104; called by muse, mutect2, varscan2
- AGBL1 | c.591C>A p.D197E | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- DNAJB1 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.337); called by muse, mutect2
- MAPKBP1 | c.376C>A p.Q126K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2
- MGA | c.4090C>A p.P1364T | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2
- PAQR9 | c.1048G>T p.V350L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PNLIPRP2 | c.694C>A p.L232I | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.36); called by muse, mutect2
- PLXNA4 | c.4635G>T p.R1545= | Silent (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- ETV4 | c.60+10G>T | Intron (SNP) | VAF 3/16 reads (19%) | called by muse, varscan2
- RAB8A | c.*5C>A | 3'UTR (SNP) | VAF 4/43 reads (9%) | called by muse, varscan2
- RNU6-389P | chr7:55685321 C>A | 5'Flank (SNP) | VAF 4/25 reads (16%) | called by mutect2, varscan2
- SLC7A7 | c.-180-205G>T | Intron (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
